Somatic mutation profile of tumor specimen ALCH-B0GS-TTP1-A (aliquot ALCH-B0GS-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0GS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.1 years (22,302 days).
Specimen ALCH-B0GS-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb25229d-8a6a-436a-a66d-3116177eba23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0GS-NB1-A (Blood Derived Normal), aliquot ALCH-B0GS-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85fe084a-8e6b-4753-b0aa-191d2eb01333

The open-access MAF lists 341 somatic variants for this specimen: 210 protein-altering or splice-affecting, 83 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 83, Intron 27, Nonsense Mutation 10, 3'UTR 10, Frame Shift Del 5, RNA 4, 5'Flank 4, Splice Site 3, 5'UTR 3, Splice Region 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 58/335 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 22/194 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCA3 | c.785A>T p.Q262L | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as COSV57049593; called by muse, mutect2, varscan2
- ABHD11 | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV99766690; called by muse, mutect2
- AL121899.2 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs190943274; called by muse, mutect2
- ALDOB | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 57/485 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs746695387, COSV66398067, COSV66398258; called by muse, mutect2, varscan2
- BCOR | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1259098035; called by muse, mutect2, varscan2
- BRINP3 | c.1325C>G p.T442R | Missense Mutation (SNP) | VAF 24/381 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV100818362; called by muse, mutect2
- CACNA1S | c.4984A>T p.N1662Y | Missense Mutation (SNP) | VAF 28/287 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.832); catalogued as rs200772623; ClinVar: uncertain significance; called by muse, mutect2
- CD6 | c.1194G>T p.E398D | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV57843586; called by muse, mutect2, varscan2
- CD93 | c.122C>T p.S41L | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1248609729, COSV55667078; called by muse, mutect2
- CDK12 | c.971C>T p.P324L | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs1309507233; called by muse, mutect2, varscan2
- CFAP74 | c.1423C>T p.R475* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as rs889184555; called by muse, mutect2
- CHML | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.167); catalogued as COSV100087610; called by muse, mutect2
- CHRM2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV57766130; called by muse, mutect2, varscan2
- COL9A1 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283598141; called by muse, mutect2, varscan2
- CSMD2 | c.4435C>A p.P1479T | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as COSV53957856; called by muse, mutect2, varscan2
- CYP1A1 | c.667_669del p.N223del | In Frame Del (DEL) | VAF 37/295 reads (13%) | catalogued as rs762836718; called by pindel, varscan2
- CYP1B1 | c.4G>C p.G2R | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs778201904; called by muse, mutect2
- DCAF1 | c.1099G>A p.D367N | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.987); catalogued as COSV60042880; called by muse, mutect2, varscan2
- DPAGT1 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 24/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs745872044, CM145535, COSV53827899; ClinVar: uncertain significance; called by muse, mutect2
- ELANE | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs200449787, CD112155, COSV55048297; called by muse, mutect2, varscan2
- EML6 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 27/238 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62872608; called by muse, mutect2, varscan2
- ESRRG | c.1328A>G p.K443R | Missense Mutation (SNP) | VAF 60/230 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV63181998; called by muse, mutect2, varscan2
- ESYT3 | c.1000T>C p.Y334H | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1337730130; called by muse, mutect2, varscan2
- FBXW7 | c.1676T>C p.L559P (on ENST00000281708 / NM_001349798.2; = p.L479P on NM_018315.5) | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55917241; called by muse, mutect2, varscan2
- FGD1 | c.191C>G p.S64W | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV64308472; called by muse, mutect2, varscan2
- FGFR2 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.286); catalogued as COSV100337466; called by muse, mutect2
- GAB1 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53754072, COSV99528293; called by muse, mutect2, varscan2
- GRIN2A | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 67/505 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV58021938; called by muse, mutect2, varscan2
- HDC | c.999C>G p.I333M | Missense Mutation (SNP) | VAF 25/431 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as rs755119621; called by muse, mutect2
- HRNR | c.1147C>A p.Q383K | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs921378070; called by muse, mutect2, varscan2
- HTR1B | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (1); PolyPhen probably damaging (0.986); catalogued as COSV64051695; called by muse, mutect2, varscan2
- ITPR1 | c.7853G>C p.R2618T (on ENST00000354582; = p.R2563T on NM_002222.7) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56973725; called by muse, mutect2
- LRFN5 | c.2018C>G p.S673* | Nonsense Mutation (SNP) | VAF 36/303 reads (12%) | catalogued as COSV53263890, COSV53269559; called by muse, mutect2, varscan2
- LRP1B | c.8104G>T p.D2702Y | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67257857; called by muse, mutect2
- LRP6 | c.3811G>C p.D1271H | Missense Mutation (SNP) | VAF 13/393 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53783657; called by muse, mutect2
- LRRTM1 | c.678C>A p.F226L | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99703331; called by muse, mutect2, varscan2
- MFSD11 | c.1267T>G p.F423V | Missense Mutation (SNP) | VAF 33/289 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as COSV99054496; called by muse, mutect2, varscan2
- MUC16 | c.32119G>T p.D10707Y | Missense Mutation (SNP) | VAF 8/165 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.967); catalogued as COSV67477775; called by muse, mutect2
- MYO16 | c.3611C>A p.A1204D | Missense Mutation (SNP) | VAF 47/284 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100697747; called by muse, mutect2, varscan2
- NCKAP5 | c.5311C>T p.R1771C | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs375675565; called by muse, mutect2
- NLRP8 | c.3083C>A p.S1028Y | Missense Mutation (SNP) | VAF 35/276 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.31); catalogued as COSV99404701; called by muse, mutect2, varscan2
- NPY1R | c.983A>T p.Q328L | Missense Mutation (SNP) | VAF 35/257 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV56714595, COSV99648760; called by muse, mutect2, varscan2
- NUDCD1 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758416339; called by muse, mutect2
- OR11G2 | c.319T>A p.L107M | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV62131874; called by muse, mutect2, varscan2
- OR1C1 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV101376173; called by muse, mutect2
- OR2W3 | c.75G>T p.R25S | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV64456091; called by muse, varscan2
- OR4N5 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 64/332 reads (19%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as COSV61320601; called by muse, mutect2, varscan2
- OR8H1 | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV57294904, COSV57295801; called by muse, mutect2, varscan2
- OR8K1 | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.114); catalogued as COSV99687148; called by muse, varscan2
- PAPPA2 | c.1938C>G p.D646E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); catalogued as COSV62780434; called by muse, mutect2, varscan2
- PCDH10 | c.922G>T p.G308C | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52101709; called by muse, mutect2, varscan2
- PCDHAC1 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.618); catalogued as rs1387102396, COSV53846371; called by muse, mutect2, varscan2
- PIK3C3 | c.2575A>C p.M859L | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56281486; called by muse, mutect2
- PKMYT1 | c.193C>A p.R65S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766487784; called by muse, mutect2
- PLEC | c.6754G>T p.E2252* (on ENST00000322810 / NM_201380.4; = p.E2142* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 21/103 reads (20%) | catalogued as COSV59640479; called by muse, mutect2, varscan2
- POLR1B | c.3007C>T p.R1003C | Missense Mutation (SNP) | VAF 53/332 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54503621; called by muse, mutect2, varscan2
- PPFIA2 | c.130C>A p.R44S | Missense Mutation (SNP) | VAF 50/350 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV61018791, COSV61037432; called by muse, mutect2, varscan2
- PRAMEF18 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 31/647 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); catalogued as rs1269731483; called by muse, mutect2
- PUM1 | c.2324-1G>T p.X775_splice | Splice Site (SNP) | VAF 14/65 reads (22%) | catalogued as COSV57084266; called by muse, mutect2
- RFWD3 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as rs201075680, COSV63099395; called by muse, mutect2
- RGPD3 | c.1640G>A p.G547E | Missense Mutation (SNP) | VAF 43/335 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as COSV58739660; called by muse, mutect2, varscan2
- SBNO2 | c.1476G>C p.E492D | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100683817; called by muse, mutect2
- SHKBP1 | c.187-5C>G | Splice Region (SNP) | VAF 10/187 reads (5%) | catalogued as rs945279343; called by muse, mutect2
- SIPA1L3 | c.1441G>C p.E481Q | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55920986; called by muse, mutect2
- SLC26A6 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.403); catalogued as COSV50839459; called by muse, mutect2, varscan2
- SMARCB1 | c.398A>T p.N133I (on ENST00000263121; = p.N179I on NM_003073.5) | Missense Mutation (SNP) | VAF 113/521 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV54094456, COSV99574704; called by muse, mutect2, varscan2
- STYXL2 | c.3251C>A p.A1084D | Missense Mutation (SNP) | VAF 102/484 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99609553; called by muse, mutect2, varscan2
- SUGT1 | c.39-1G>A p.X13_splice | Splice Site (SNP) | VAF 12/188 reads (6%) | catalogued as COSV59423787; called by muse, mutect2
- TENM1 | c.2585G>C p.R862P | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100949310, COSV64433126; called by muse, mutect2
- TNFAIP6 | c.488G>A p.W163* | Nonsense Mutation (SNP) | VAF 36/291 reads (12%) | catalogued as rs200453016; called by muse, mutect2, varscan2
- TP53 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 58/310 reads (19%) | catalogued as COSV52679869, COSV53267121, COSV53424574; called by muse, mutect2, varscan2
- TRPC3 | c.1536G>A p.M512I (on ENST00000379645 / NM_001366479.2; = p.M439I on NM_003305.2) | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV53372379; called by muse, mutect2, varscan2
- TRPM6 | c.4318C>G p.L1440V | Missense Mutation (SNP) | VAF 24/728 reads (3%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV100666241, COSV62517359; called by muse, mutect2
- UHRF1BP1L | c.3685A>T p.S1229C | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV54434573; called by muse, mutect2, varscan2
- UNC79 | c.2802T>C p.A934= (on ENST00000393151 / NM_001346218.2; = p.A757= on NM_020818.5) | Splice Region (SNP) | VAF 12/75 reads (16%) | catalogued as rs936541158; called by muse, mutect2, varscan2
- USH2A | c.11764G>T p.A3922S | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs745965437; called by muse, mutect2, varscan2
- VPS13A | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 55/251 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs201567434; called by muse, mutect2, varscan2
- WDR62 | c.3137C>A p.P1046H | Missense Mutation (SNP) | VAF 51/321 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.346); catalogued as COSV99543680; called by muse, mutect2, varscan2
- ZNF248 | c.851G>T p.R284M | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.436); catalogued as COSV99050278; called by muse, mutect2, varscan2
- ZNF507 | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as COSV100322024; called by muse, mutect2
- ABCA12 | c.2817G>A p.M939I (on ENST00000272895 / NM_173076.3; = p.M621I on NM_015657.3) | Missense Mutation (SNP) | VAF 54/311 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ABCG8 | c.1603G>C p.V535L | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- AC093323.1 | c.62G>T p.S21I | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.617); called by muse, varscan2
- ACSS3 | c.1934C>A p.T645N | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAMTS20 | c.1900G>T p.G634C | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRD1 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- AGA | c.352G>C p.V118L | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AKAP4 | c.276+1G>A p.X92_splice | Splice Site (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- ALMS1 | c.2777T>C p.L926P | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.708); called by muse, mutect2
- ALMS1 | c.3707C>T p.S1236F | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2
- ANXA1 | c.26A>T p.K9M | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- AOX1 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.081); called by muse, mutect2
- ARHGEF11 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARMC4 | c.747T>A p.Y249* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | called by muse, mutect2, varscan2
- ASTN2 | c.3902A>T p.E1301V (on ENST00000313400 / NM_001365069.1; = p.E1250V on NM_014010.5) | Missense Mutation (SNP) | VAF 83/484 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- B3GNT6 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BROX | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 68/263 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- C11orf52 | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 50/278 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- C16orf70 | c.118A>G p.K40E | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); called by muse, mutect2
- C8A | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- CACNA1E | c.6014C>G p.T2005S | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CD47 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CGNL1 | c.2234C>G p.A745G | Missense Mutation (SNP) | VAF 44/317 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CHRDL2 | c.578G>C p.G193A | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.341); called by muse, mutect2
- CLCN1 | c.1027T>A p.F343I | Missense Mutation (SNP) | VAF 62/440 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL2A1 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL4A3 | c.4177C>G p.P1393A | Missense Mutation (SNP) | VAF 45/327 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CPT1A | c.2149G>C p.D717H | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CSMD3 | c.4117G>T p.A1373S (on ENST00000297405 / NM_001363185.1; = p.A1269S on NM_052900.3) | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CYP7B1 | c.125G>T p.R42I | Missense Mutation (SNP) | VAF 64/422 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DDX24 | c.77T>A p.V26E | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- DDX6 | c.857A>C p.K286T | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DEPDC4 | c.27_28del p.E10Afs*12 | Frame Shift Del (DEL) | VAF 15/90 reads (17%) | called by pindel, varscan2
- DLG3 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- DLG3 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DOK6 | c.454T>A p.Y152N | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DSTYK | c.164T>A p.I55N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- DYNC2H1 | c.7861G>A p.D2621N | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2
- ERBB4 | c.3208G>T p.G1070C | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2
- ERCC6L2 | c.1532A>T p.K511M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- FAM110B | c.854dup p.E286Gfs*15 | Frame Shift Ins (INS) | VAF 42/402 reads (10%) | called by mutect2, pindel
- FAM135B | c.3690del p.R1232Gfs*40 | Frame Shift Del (DEL) | VAF 36/320 reads (11%) | called by mutect2, pindel, varscan2
- FAM186A | c.2917A>G p.R973G | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM47A | c.534G>T p.E178D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.85); called by muse, mutect2
- FLI1 | c.147C>A p.N49K | Missense Mutation (SNP) | VAF 48/331 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- FLRT2 | c.1160C>G p.S387C | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2
- FMN2 | c.1878del p.P627Hfs*41 | Frame Shift Del (DEL) | VAF 14/128 reads (11%) | called by mutect2, varscan2
- GATB | c.1537C>G p.P513A | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.266); called by mutect2, varscan2
- GFRA1 | c.902A>G p.Y301C | Missense Mutation (SNP) | VAF 51/416 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GON4L | c.2384C>G p.A795G | Missense Mutation (SNP) | VAF 23/361 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2
- GPR119 | c.920T>C p.F307S | Missense Mutation (SNP) | VAF 50/117 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GREB1 | c.4472C>A p.A1491D | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- GRXCR1 | c.264T>G p.S88R | Missense Mutation (SNP) | VAF 14/398 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- HAUS3 | c.1220A>C p.N407T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2
- HHIPL2 | c.1175del p.G392Afs*66 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- IGKV3-15 | c.95C>G p.S32C | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- KLF8 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- KLRF1 | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAIR2 | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 42/271 reads (15%) | called by muse, mutect2, varscan2
- LCOR | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRIQ1 | c.2009A>G p.K670R | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MAP4K4 | c.1347G>T p.E449D | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MINDY2 | c.1303G>T p.V435F | Missense Mutation (SNP) | VAF 40/250 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- MLF1 | c.367G>T p.V123F | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- MRGPRX2 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.036); called by muse, mutect2
- MSRA | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- MTMR2 | c.990C>A p.N330K | Missense Mutation (SNP) | VAF 54/443 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC16 | c.8849C>A p.A2950E | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MYBPH | c.101C>A p.A34E | Missense Mutation (SNP) | VAF 54/430 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MYH8 | c.5151G>T p.Q1717H | Missense Mutation (SNP) | VAF 80/438 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- OOSP2 | c.347G>T p.R116M | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR13A1 | c.544C>A p.L182M | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OR1S2 | c.587C>A p.P196H | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- OR4C16 | c.837T>A p.F279L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OR52D1 | c.506T>G p.L169R | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR52N1 | c.692C>A p.S231* | Nonsense Mutation (SNP) | VAF 51/351 reads (15%) | called by muse, varscan2
- OR5K3 | c.702A>T p.K234N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR6K2 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 30/400 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR9I1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- OTOA | c.1855T>A p.C619S (on ENST00000286149; = p.C605S on NM_144672.4) | Missense Mutation (SNP) | VAF 55/435 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OTOG | c.2567G>C p.G856A | Missense Mutation (SNP) | VAF 24/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PCDHB5 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 43/231 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX2 | c.392C>A p.S131* | Nonsense Mutation (SNP) | VAF 54/309 reads (17%) | called by muse, mutect2, varscan2
- PIEZO2 | c.1428G>C p.R476S | Missense Mutation (SNP) | VAF 36/289 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, varscan2
- PKHD1 | c.5747C>A p.T1916N | Missense Mutation (SNP) | VAF 40/256 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLA2G4D | c.2135A>T p.E712V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- PNLIPRP3 | c.199T>A p.Y67N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- PNLIPRP3 | c.1296G>T p.L432F | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, mutect2
- PPP1R12C | c.1207C>T p.P403S | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- PRAG1 | c.1320G>C p.Q440H | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PSD4 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- PTGER3 | c.1223T>A p.V408E | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH2R | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PTPN11 | c.1225-7A>T | Splice Region (SNP) | VAF 58/395 reads (15%) | called by muse, mutect2, varscan2
- RBM46 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2
- RFC3 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- SAGE1 | c.962C>A p.P321Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SALL4 | c.1837C>G p.L613V | Missense Mutation (SNP) | VAF 151/687 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SHTN1 | c.1426G>C p.E476Q | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SIPA1 | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLFN14 | c.2378A>G p.Q793R | Missense Mutation (SNP) | VAF 20/333 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.086); called by muse, mutect2
- SMARCA4 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 18/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SNX25 | c.175G>T p.V59F | Missense Mutation (SNP) | VAF 30/227 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SP3 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPTLC2 | c.823G>T p.A275S | Missense Mutation (SNP) | VAF 32/297 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- STX1A | c.421T>A p.Y141N | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SYNE1 | c.19174A>T p.T6392S (on ENST00000367255 / NM_182961.4; = p.T6321S on NM_033071.3) | Missense Mutation (SNP) | VAF 30/410 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- SYNE2 | c.14810A>T p.H4937L | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- TAB2 | c.2012C>T p.T671I | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); called by muse, mutect2
- TCEAL1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.895); called by muse, mutect2
- TDRD6 | c.1706T>C p.L569S | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TET2 | c.5074A>T p.K1692* | Nonsense Mutation (SNP) | VAF 51/324 reads (16%) | called by muse, mutect2, varscan2
- TGFBR3L | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMOD2 | c.902A>T p.E301V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPTE | c.1154T>A p.V385E (on ENST00000618007 / NM_199261.4; = p.V367E on NM_199259.4) | Missense Mutation (SNP) | VAF 26/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRIM49B | c.30G>C p.Q10H | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.115); called by muse, mutect2
- TXK | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 17/175 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- UBR3 | c.383T>A p.F128Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- UBR3 | c.384C>A p.F128L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.228); called by muse, varscan2
- UNC13C | c.4603C>A p.P1535T | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VPS13C | c.10708A>G p.I3570V (on ENST00000644861 / NM_020821.3; = p.I3527V on NM_017684.5) | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- WSCD1 | c.1150T>G p.F384V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- XIRP2 | c.1964del p.K655Rfs*4 (on ENST00000628543; = p.K830Rfs*4 on NM_152381.6) | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | called by mutect2, pindel, varscan2
- XRRA1 | c.288C>G p.H96Q | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- YIPF4 | c.654A>T p.E218D | Missense Mutation (SNP) | VAF 33/231 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ZNF530 | c.1481G>T p.S494I | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- ZNF536 | c.3570G>T p.M1190I | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2
- ZNF804B | c.2399G>T p.R800I | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ABCA9 | c.4197C>T p.I1399= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs749228341, COSV60630238; called by muse, mutect2
- ADGRE3 | c.228T>C p.S76= | Silent (SNP) | VAF 24/206 reads (12%) | catalogued as rs761975631; called by muse, mutect2, varscan2
- ADH1B | c.474G>T p.V158= | Silent (SNP) | VAF 37/500 reads (7%) | called by muse, mutect2
- ADIPOR2 | c.459C>G p.L153= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs750557873; called by muse, mutect2
- AK7 | c.804C>T p.H268= | Silent (SNP) | VAF 31/294 reads (11%) | catalogued as rs914695788, COSV50874137; called by muse, mutect2, varscan2
- APOB | c.4158G>A p.R1386= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV51931048; called by muse, mutect2, varscan2
- ARHGAP40 | c.711C>A p.A237= | Silent (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- ARHGEF6 | c.2166G>A p.K722= | Silent (SNP) | VAF 90/225 reads (40%) | called by muse, mutect2, varscan2
- ASTL | c.705G>A p.V235= | Silent (SNP) | VAF 37/227 reads (16%) | called by muse, mutect2, varscan2
- BEST2 | c.1239C>A p.R413= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- BRWD3 | c.414G>A p.V138= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as COSV64747796; called by muse, mutect2
- BUB3 | c.318A>T p.P106= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- CCDC150 | c.1590A>G p.L530= | Silent (SNP) | VAF 41/206 reads (20%) | called by muse, mutect2, varscan2
- CCDC50 | c.966C>T p.L322= | Silent (SNP) | VAF 30/232 reads (13%) | catalogued as COSV66667537; called by muse, mutect2, varscan2
- CCDC88A | c.4167T>A p.P1389= | Silent (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- CLEC4G | c.675G>A p.L225= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV61003773; called by muse, mutect2, varscan2
- COG8 | c.1036C>T p.L346= | Silent (SNP) | VAF 49/310 reads (16%) | called by muse, mutect2, varscan2
- COMP | c.2172C>T p.V724= | Silent (SNP) | VAF 35/272 reads (13%) | called by muse, mutect2, varscan2
- CRACDL | c.2190C>T p.L730= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs377246442; called by muse, mutect2
- DDX5 | c.1728A>G p.Q576= | Silent (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- DENND5A | c.45C>T p.F15= | Silent (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- DNPEP | c.819G>A p.L273= | Silent (SNP) | VAF 31/165 reads (19%) | called by muse, mutect2, varscan2
- ECM1 | c.768C>T p.H256= | Silent (SNP) | VAF 37/128 reads (29%) | called by muse, mutect2, varscan2
- FAM234A | c.1398C>T p.R466= | Silent (SNP) | VAF 32/181 reads (18%) | catalogued as rs375392908; called by muse, mutect2, varscan2
- FOXA2 | c.384C>T p.A128= (on ENST00000377115 / NM_153675.3; = p.A134= on NM_021784.5) | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- GDPD5 | c.639C>A p.I213= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- GNL1 | c.1794T>G p.P598= | Silent (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
- H3C10 | c.243C>A p.T81= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs139819774; called by muse, mutect2
- IGKV6D-21 | c.213C>T p.S71= | Silent (SNP) | VAF 34/282 reads (12%) | catalogued as rs543190921; called by muse, mutect2, varscan2
- IGSF11 | c.1116G>A p.L372= (on ENST00000393775 / NM_001015887.3; = p.L371= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- IL20RA | c.1089T>A p.A363= | Silent (SNP) | VAF 65/313 reads (21%) | called by muse, mutect2, varscan2
- KIR2DL4 | c.522G>T p.T174= (on ENST00000396284; = p.T135= on NM_001080770.2) | Silent (SNP) | VAF 18/106 reads (17%) | catalogued as rs767101253; called by muse, mutect2
- KRTAP4-11 | c.507C>A p.S169= | Silent (SNP) | VAF 35/239 reads (15%) | called by muse, mutect2
- LRRIQ3 | c.1204C>A p.R402= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV63041638; called by muse, mutect2, varscan2
- MARCHF3 | c.588C>T p.Y196= | Silent (SNP) | VAF 51/196 reads (26%) | called by muse, mutect2, varscan2
- MKX | c.792G>T p.V264= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2
- MYL7 | c.441C>T p.F147= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs549853546, COSV56267917; called by muse, mutect2, varscan2
- NUF2 | c.228A>T p.P76= | Silent (SNP) | VAF 38/144 reads (26%) | called by muse, mutect2, varscan2
- OBSCN | c.5169C>T p.C1723= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV99478615; called by muse, mutect2
- OLA1 | c.753G>T p.V251= | Silent (SNP) | VAF 41/196 reads (21%) | called by muse, mutect2, varscan2
- OR11L1 | c.444C>T p.S148= | Silent (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- OR2G6 | c.459C>A p.L153= | Silent (SNP) | VAF 57/224 reads (25%) | catalogued as rs1018629098, COSV58575237; called by muse, mutect2, varscan2
- OR5D18 | c.606T>C p.F202= | Silent (SNP) | VAF 36/426 reads (8%) | called by muse, mutect2
- OR6N1 | c.639G>T p.L213= | Silent (SNP) | VAF 58/273 reads (21%) | catalogued as rs766760882, COSV100625215; called by muse, mutect2, varscan2
- ORC2 | c.831C>T p.S277= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs775344046, COSV52238560; called by muse, mutect2, varscan2
- PCLO | c.5184T>C p.G1728= | Silent (SNP) | VAF 12/194 reads (6%) | catalogued as COSV61635336; called by muse, mutect2
- PDE11A | c.2724A>G p.L908= | Silent (SNP) | VAF 50/479 reads (10%) | called by muse, mutect2, varscan2
- PIANP | c.429C>T p.P143= | Silent (SNP) | VAF 50/289 reads (17%) | catalogued as COSV57707714; called by muse, mutect2, varscan2
- PIF1 | c.219C>T p.A73= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs1311805767; called by muse, mutect2
- PLEC | c.8898C>G p.A2966= (on ENST00000322810 / NM_201380.4; = p.A2856= on NM_000445.5) | Silent (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- PLEC | c.5907G>A p.E1969= (on ENST00000322810 / NM_201380.4; = p.E1859= on NM_000445.5) | Silent (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.1539G>T p.R513= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- PRDM9 | c.1467G>T p.V489= | Silent (SNP) | VAF 35/252 reads (14%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.957A>C p.P319= | Silent (SNP) | VAF 72/455 reads (16%) | called by muse, mutect2, varscan2
- RFX6 | c.102C>A p.G34= | Silent (SNP) | VAF 49/237 reads (21%) | called by muse, mutect2, varscan2
- SFRP4 | c.174C>T p.I58= | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV52258083; called by muse, mutect2
- SH3PXD2A | c.2610G>A p.L870= (on ENST00000369774 / NM_001365079.1; = p.L842= on NM_014631.2) | Silent (SNP) | VAF 40/242 reads (17%) | called by muse, mutect2, varscan2
- STYXL1 | c.207G>A p.E69= | Silent (SNP) | VAF 62/329 reads (19%) | called by muse, mutect2, varscan2
- STYXL2 | c.3252C>T p.A1084= | Silent (SNP) | VAF 101/494 reads (20%) | catalogued as COSV54810332; called by muse, mutect2, varscan2
- SUCLG1 | c.63C>T p.L21= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as rs982734922, COSV67265520, COSV67265626; called by muse, mutect2
- TAF1A | c.1149T>C p.H383= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- TDRD12 | c.2406G>T p.A802= | Silent (SNP) | VAF 33/236 reads (14%) | called by muse, mutect2, varscan2
- TENM2 | c.192C>T p.L64= | Silent (SNP) | VAF 43/223 reads (19%) | catalogued as COSV72862981; called by muse, mutect2, varscan2
- TMEM132C | c.762A>T p.P254= | Silent (SNP) | VAF 7/56 reads (13%) | called by muse, mutect2, varscan2
- TMEM178B | c.174C>T p.N58= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as rs1477939591; called by muse, mutect2, varscan2
- TMPRSS15 | c.1284T>C p.H428= | Silent (SNP) | VAF 23/209 reads (11%) | called by muse, mutect2, varscan2
- TRIM24 | c.699G>T p.L233= | Silent (SNP) | VAF 22/174 reads (13%) | called by muse, mutect2, varscan2
- TSPEAR | c.729A>T p.P243= | Silent (SNP) | VAF 33/185 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.23406G>C p.V7802= (on ENST00000591111; = p.V6875= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/293 reads (9%) | called by muse, mutect2
- TYW1 | c.762C>A p.G254= | Silent (SNP) | VAF 29/220 reads (13%) | called by muse, mutect2, varscan2
- UHRF1BP1L | c.3684C>T p.I1228= | Silent (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- UMOD | c.303G>A p.S101= | Silent (SNP) | VAF 32/175 reads (18%) | catalogued as rs370600033, COSV100208412; called by muse, mutect2, varscan2
- VN1R4 | c.15T>C p.Y5= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- VN1R5 | c.651T>C p.F217= | Silent (SNP) | VAF 17/160 reads (11%) | called by muse, mutect2, varscan2
- VPS50 | c.2070T>G p.A690= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- VSTM2B | c.576C>T p.T192= | Silent (SNP) | VAF 18/127 reads (14%) | called by muse, mutect2, varscan2
- VTI1A | c.66G>A p.K22= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- WDR64 | c.2349T>A p.P783= | Silent (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- XKRX | c.237T>C p.I79= | Silent (SNP) | VAF 50/131 reads (38%) | called by muse, mutect2, varscan2
- YARS1 | c.1566G>C p.L522= | Silent (SNP) | VAF 10/277 reads (4%) | called by muse, mutect2
- ZBTB20 | c.1131G>T p.S377= (on ENST00000474710 / NM_001164342.2; = p.S304= on NM_015642.6 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- ZFPM1 | c.2523C>T p.P841= | Silent (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- ZHX1 | c.1779T>C p.L593= | Silent (SNP) | VAF 58/189 reads (31%) | called by muse, mutect2, varscan2
- ABL2 | c.158-9596C>T | Intron (SNP) | VAF 26/252 reads (10%) | called by muse, mutect2, varscan2
- AIRE | c.880-260C>A | Intron (SNP) | VAF 25/275 reads (9%) | called by muse, mutect2
- AL772337.1 | n.857+11C>G | Intron (SNP) | VAF 59/312 reads (19%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1635+2103G>T | Intron (SNP) | VAF 36/226 reads (16%) | catalogued as rs1185013379; called by muse, mutect2, varscan2
- ASCL1 | c.*16C>T | 3'UTR (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- CLPTM1 | c.*87C>T | 3'UTR (SNP) | VAF 17/93 reads (18%) | catalogued as rs751002831; called by muse, mutect2, varscan2
- CSMD3 | c.401+25T>A | Intron (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- D2HGDH | c.1141-701G>C | Intron (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- DCAF17 | c.*745G>T | 3'UTR (SNP) | VAF 14/121 reads (12%) | called by muse, mutect2, varscan2
- ELMOD1 | c.-86+586C>A | Intron (SNP) | VAF 2/15 reads (13%) | called by muse, mutect2
- FABP7 | c.-5C>A | 5'UTR (SNP) | VAF 34/179 reads (19%) | called by muse, varscan2
- FOLR3 | c.169-32G>A | Intron (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- GALNT9 | c.1077+130G>A | Intron (SNP) | VAF 18/127 reads (14%) | catalogued as rs1324352103; called by muse, varscan2
- KCNK12 | c.*8598T>A | 3'UTR (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- KCTD15 | c.-6G>T | 5'UTR (SNP) | VAF 15/160 reads (9%) | called by muse, mutect2
- KRT40 | c.688-151A>G | Intron (SNP) | VAF 28/278 reads (10%) | called by muse, mutect2, varscan2
- KRT8P11 | n.65T>A | RNA (SNP) | VAF 32/344 reads (9%) | called by muse, mutect2
- LRTOMT | c.82+281C>T | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- MGAM | c.4618+1956G>A | Intron (SNP) | VAF 27/270 reads (10%) | catalogued as rs184831460; called by muse, mutect2
- MIR216A | n.57C>G | RNA (SNP) | VAF 25/123 reads (20%) | catalogued as rs1471553370; called by muse, mutect2, varscan2
- NOC2LP2 | n.1505C>T | RNA (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- OR52A4P | n.760C>A | RNA (SNP) | VAF 8/47 reads (17%) | catalogued as rs1292120382; called by muse, mutect2, varscan2
- OTOF | c.3864+27C>A | Intron (SNP) | VAF 40/305 reads (13%) | called by muse, mutect2, varscan2
- OVCH1 | c.893-589A>T | Intron (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- PBX1 | c.*2675del | 3'UTR (DEL) | VAF 60/255 reads (24%) | called by mutect2, pindel, varscan2
- PNPLA6 | c.-9A>T | 5'UTR (SNP) | VAF 31/181 reads (17%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | chr19:10106305 del C | 5'Flank (DEL) | VAF 6/37 reads (16%) | called by mutect2, pindel, varscan2
- PPFIBP1 | c.-36+21211A>T | Intron (SNP) | VAF 28/170 reads (16%) | called by muse, mutect2, varscan2
- PTMA | chr2:231707784 del G | 5'Flank (DEL) | VAF 28/176 reads (16%) | called by mutect2, pindel, varscan2
- REG1B | c.*17del | 3'UTR (DEL) | VAF 17/135 reads (13%) | called by mutect2, pindel, varscan2
- RPL4 | chr15:66505320 G>A | 5'Flank (SNP) | VAF 18/94 reads (19%) | catalogued as COSV57181808; called by muse, mutect2, varscan2
- RSPO4 | c.*16A>G | 3'UTR (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- SLC14A1 | c.-22+2350C>A | Intron (SNP) | VAF 17/147 reads (12%) | catalogued as rs982814472, COSV58931817; called by muse, mutect2, varscan2
- SLC45A2 | c.1368+20C>T | Intron (SNP) | VAF 22/276 reads (8%) | catalogued as COSV56874540; called by muse, mutect2
- SLC4A10 | c.*92G>A | 3'UTR (SNP) | VAF 14/219 reads (6%) | called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-45845A>T | Intron (SNP) | VAF 20/140 reads (14%) | called by muse, mutect2, varscan2
- SPAG11B | c.*68C>G | 3'UTR (SNP) | VAF 33/498 reads (7%) | catalogued as COSV52499308; called by muse, mutect2
- TMTC1 | c.939-26613T>A | Intron (SNP) | VAF 42/285 reads (15%) | called by muse, mutect2, varscan2
- TNFRSF1A | c.552-21C>T | Intron (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- TPCN1 | c.-125-1439G>T | Intron (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.34264+2937C>T | Intron (SNP) | VAF 40/215 reads (19%) | catalogued as COSV60310103; called by muse, mutect2, varscan2
- VAPB | c.*4573C>G | 3'UTR (SNP) | VAF 48/508 reads (9%) | called by muse, mutect2
- WT1 | c.1304-18C>G | Intron (SNP) | VAF 54/270 reads (20%) | called by muse, mutect2, varscan2
- ZIC3 | c.1061-36C>A | Intron (SNP) | VAF 73/162 reads (45%) | catalogued as COSV54975348; called by muse, mutect2, varscan2
- ZNF131 | c.1055-5349T>C | Intron (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- ZNF141 | c.226+13778A>G | Intron (SNP) | VAF 12/102 reads (12%) | catalogued as rs1553851525; called by mutect2, varscan2
- ZNF566 | c.9+26G>A | Intron (SNP) | VAF 16/167 reads (10%) | called by mutect2, varscan2
- ZNF578 | chr19:52451306 C>G | 5'Flank (SNP) | VAF 11/212 reads (5%) | called by muse, mutect2
